Somatic mutation profile of tumor specimen TCGA-KP-A3W0-01A (aliquot TCGA-KP-A3W0-01A-21D-A228-09) from TCGA case TCGA-KP-A3W0, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G3; Age at diagnosis: 72.2 years (26,378 days).
Specimen TCGA-KP-A3W0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 17deb042-da0e-424e-82b7-942752b88f86.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KP-A3W0-10A (Blood Derived Normal), aliquot TCGA-KP-A3W0-10A-01D-A22A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b513d67e-7f82-4f04-b95e-a9b7ca30e0f0

The open-access MAF lists 43 somatic variants for this specimen: 38 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 3, Nonsense Mutation 3, Frame Shift Del 2, RNA 1, 5'UTR 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPOP | c.349A>G p.M117V | Missense Mutation (SNP) | VAF 11/25 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV61652945; called by muse, mutect2, varscan2
- TP53 | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 11/22 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.798); catalogued as rs28934874, CM012662, CM120847, CM941326, COSV52661698, COSV52676321, COSV52676982, COSV52701855; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AP3S2 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.834); catalogued as rs139910320; called by muse, mutect2, varscan2
- ASXL1 | c.1992C>G p.S664R | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.599); catalogued as COSV100039716, COSV60103128; called by muse, mutect2, varscan2
- CERCAM | c.1550C>G p.A517G | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV100864042; called by muse, mutect2, varscan2
- CHRM5 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs878903159, COSV101271969; called by muse, mutect2, varscan2
- CLCN5 | c.365G>T p.W122L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100260234; called by muse, mutect2, varscan2
- COLEC12 | c.583C>A p.Q195K | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.98); catalogued as COSV101232094, COSV68371412; called by muse, mutect2, varscan2
- DOK4 | c.667G>A p.V223I | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs146675149; called by muse, mutect2, varscan2
- DSG3 | c.1459G>A p.D487N | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.15); catalogued as rs771845317, COSV57125840; called by muse, mutect2, varscan2
- DTD1 | c.460A>G p.T154A | Missense Mutation (SNP) | VAF 17/28 reads (61%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV101079895; called by muse, mutect2, varscan2
- FBN2 | c.2083C>T p.R695C | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747447916, COSV52545649; called by muse, mutect2, varscan2
- H2BC21 | c.10C>T p.P4S | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs201449104, COSV58611338; called by muse, mutect2, varscan2
- HELZ2 | c.7090A>G p.M2364V (on ENST00000467148 / NM_001037335.2; = p.M1795V on NM_033405.3) | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.926); catalogued as COSV64442410; called by muse, mutect2, varscan2
- IMPG2 | c.1392A>T p.L464F | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.888); catalogued as COSV99515728; called by muse, mutect2, varscan2
- INSYN2A | c.484T>C p.C162R | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.295); catalogued as rs200216671, COSV99730403; called by muse, mutect2, varscan2
- KAT2A | c.556G>T p.V186F | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV99863593; called by muse, mutect2, varscan2
- KCNA4 | c.82C>T p.R28W | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs1225405166, COSV100069040; called by muse, mutect2, varscan2
- MYH6 | c.826T>C p.F276L | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV100676694; called by muse, mutect2, varscan2
- PARD3 | c.3458G>A p.R1153Q | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs776935606, COSV100632344, COSV100633664; called by muse, mutect2, varscan2
- PCDHA13 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs899488409, COSV56558931; called by muse, mutect2, varscan2
- PCDHGA1 | c.2420A>T p.Q807L | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); catalogued as COSV100966000; called by muse, mutect2, varscan2
- PFKM | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.76); catalogued as COSV100402535; called by mutect2, varscan2
- PLEK2 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as COSV99371811; called by muse, mutect2, varscan2
- PSG2 | c.292C>T p.R98* | Nonsense Mutation (SNP) | VAF 150/219 reads (68%) | catalogued as rs367816200; called by muse, mutect2, varscan2
- PTCHD3 | c.338G>A p.R113H | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.148); catalogued as rs865938215, COSV71257321; called by muse, mutect2, varscan2
- SNX29 | c.2265G>C p.E755D | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.057); catalogued as COSV100029130; called by muse, mutect2, varscan2
- SOS1 | c.266A>C p.D89A | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101217029; called by muse, mutect2, varscan2
- TNFRSF9 | c.643C>T p.R215W | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs143524950; called by muse, mutect2, varscan2
- TRPC4 | c.2015G>A p.W672* | Nonsense Mutation (SNP) | VAF 4/70 reads (6%) | catalogued as COSV59020579; called by muse, mutect2
- USF3 | c.425A>T p.Q142L | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.562); catalogued as COSV100325440; called by muse, mutect2, varscan2
- WASHC1 | c.1076C>A p.S359Y | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs746128171; called by muse, mutect2
- ZNF273 | c.1076C>G p.S359* | Nonsense Mutation (SNP) | VAF 15/32 reads (47%) | catalogued as COSV100139362; called by muse, mutect2, varscan2
- ARHGAP35 | c.4284del p.F1428Lfs*371 | Frame Shift Del (DEL) | VAF 29/55 reads (53%) | called by mutect2, pindel, varscan2
- HIVEP3 | c.1207C>A p.Q403K | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.355); called by muse, mutect2
- PPP2R1A | c.198_200del p.L67del | In Frame Del (DEL) | VAF 62/96 reads (65%) | called by pindel, varscan2
- RESF1 | c.5100_5101del p.R1701Tfs*12 | Frame Shift Del (DEL) | VAF 10/24 reads (42%) | called by mutect2, varscan2
- SHF | c.298_303+2del p.X100_splice | Splice Site (DEL) | VAF 8/24 reads (33%) | called by mutect2, pindel, varscan2
- ETS1 | c.1230C>T p.Y410= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs189020853, COSV60095947, COSV60098376; called by muse, mutect2, varscan2
- PCDHB8 | c.759T>C p.S253= | Silent (SNP) | VAF 32/162 reads (20%) | catalogued as COSV99177074; called by muse, varscan2
- RBAK | c.198G>A p.P66= | Silent (SNP) | VAF 13/67 reads (19%) | catalogued as rs576821880, COSV62332999; called by muse, mutect2, varscan2
- CLU | c.-50_-34del | 5'UTR (DEL) | VAF 8/21 reads (38%) | called by mutect2, varscan2
- HCG27 | n.519_527del | RNA (DEL) | VAF 25/64 reads (39%) | called by mutect2, pindel, varscan2
